Somatic mutation profile of tumor specimen C3N-03039-01 (aliquot CPT0235230007) from CPTAC case C3N-03039, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen C3N-03039-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c09def0-60ac-4087-af93-89ac802a5d55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03039-71 (Blood Derived Normal), aliquot CPT0235410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/475ad4d2-ca43-4490-8f8b-6741ef3f2c3b

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, 5'UTR 4, RNA 4, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 108/561 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 228/860 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.15929G>A p.R5310H | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs368944647; called by muse, mutect2, varscan2
- APOH | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs138847585; called by muse, mutect2, varscan2
- DCDC2 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV65830728; called by muse, mutect2, varscan2
- DNAJC5G | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 97/466 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs200578672, COSV56081240; called by muse, mutect2, varscan2
- DUSP21 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1386105827, COSV100173577; called by muse, mutect2, varscan2
- GKAP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs554092166, COSV64487280; called by muse, mutect2, varscan2
- HOXA3 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 125/503 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs375062129; called by muse, mutect2, varscan2
- IMPDH1 | c.179C>T p.T60M (on ENST00000470772 / NM_001142573.2; = p.T145M on NM_000883.4) | Missense Mutation (SNP) | VAF 236/1006 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs750159508; called by muse, mutect2, varscan2
- ITM2C | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as rs201325357; called by muse, mutect2, varscan2
- KDF1 | c.920del p.R307Qfs*42 | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | catalogued as COSV57672232; called by mutect2, pindel, varscan2
- KNDC1 | c.4141G>A p.G1381S | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs773807341, COSV100465233, COSV58831454; called by muse, mutect2, varscan2
- LUM | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747899454, COSV57127852; called by muse, mutect2, varscan2
- MOCOS | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 110/721 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs199870151; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 152/659 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- OGT | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 117/575 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs1326442849, COSV65480952; called by muse, mutect2, varscan2
- OR52I2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753185432, COSV57044357; called by muse, mutect2, varscan2
- PCDHGA2 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53914531; called by muse, mutect2, varscan2
- RAG2 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 137/715 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV104398641; called by muse, mutect2, varscan2
- SLITRK1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV65675004; called by muse, mutect2, varscan2
- AP4B1 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 173/763 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CEP152 | c.510A>T p.K170N | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DDX23 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 98/374 reads (26%) | called by muse, mutect2, varscan2
- DLC1 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- EGR2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMPD3 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GOPC | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 157/615 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- INAFM1 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 97/467 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- INTS1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIF13B | c.5047G>A p.G1683R | Missense Mutation (SNP) | VAF 145/552 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF2C | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAGEB5 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAGEL2 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- OR4C11 | c.768T>A p.Y256* | Nonsense Mutation (SNP) | VAF 78/421 reads (19%) | called by muse, mutect2, varscan2
- PTDSS1 | c.574A>T p.I192F | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SLIT2 | c.2709A>T p.K903N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SPTBN2 | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TGFBR1 | c.1131-2A>T p.X377_splice | Splice Site (SNP) | VAF 160/564 reads (28%) | called by mutect2, varscan2
- TPR | c.580A>G p.N194D | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- VEGFA | c.422+8G>C | Splice Region (SNP) | VAF 92/564 reads (16%) | called by muse, mutect2, varscan2
- VPS13B | c.10508T>G p.I3503S | Missense Mutation (SNP) | VAF 163/764 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- WNK4 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 144/629 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WRN | c.3877C>G p.Q1293E | Missense Mutation (SNP) | VAF 180/835 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ZNRF3 | c.203C>G p.S68W | Missense Mutation (SNP) | VAF 104/498 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZZEF1 | c.8455G>T p.V2819L | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC60 | c.1224C>A p.L408= | Silent (SNP) | VAF 91/382 reads (24%) | called by muse, mutect2, varscan2
- DGKI | c.2940C>T p.D980= | Silent (SNP) | VAF 33/249 reads (13%) | called by mutect2, varscan2
- IGLV9-49 | c.30C>T p.L10= | Silent (SNP) | VAF 53/464 reads (11%) | catalogued as rs1431998902; called by muse, mutect2, varscan2
- IL6ST | c.1023T>G p.T341= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- LRP1 | c.7192C>T p.L2398= | Silent (SNP) | VAF 38/741 reads (5%) | called by muse, mutect2
- MISP | c.489C>A p.G163= | Silent (SNP) | VAF 123/524 reads (23%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.459T>A p.P153= | Silent (SNP) | VAF 41/314 reads (13%) | called by muse, mutect2, varscan2
- PCID2 | c.576T>A p.I192= | Silent (SNP) | VAF 129/445 reads (29%) | called by muse, mutect2, varscan2
- PLIN4 | c.1002C>A p.A334= (on ENST00000301286; = p.A349= on NM_001367868.2) | Silent (SNP) | VAF 202/1200 reads (17%) | called by muse, varscan2
- SMYD5 | c.156G>A p.R52= | Silent (SNP) | VAF 105/577 reads (18%) | called by muse, mutect2, varscan2
- TMEM174 | c.327G>A p.P109= | Silent (SNP) | VAF 123/975 reads (13%) | catalogued as rs770962988, COSV57114477; called by muse, mutect2, varscan2
- TNN | c.1845C>T p.N615= | Silent (SNP) | VAF 170/497 reads (34%) | catalogued as rs564187493, COSV53437634; called by muse, mutect2, varscan2
- ZCCHC18 | c.1101C>T p.N367= | Silent (SNP) | VAF 80/390 reads (21%) | called by muse, mutect2, varscan2
- AGGF1 | c.-331_-326del | 5'UTR (DEL) | VAF 34/229 reads (15%) | called by mutect2, pindel, varscan2
- AP3S1 | c.-11C>A | 5'UTR (SNP) | VAF 37/388 reads (10%) | called by muse, mutect2
- CELF2 | c.1076-2339C>T | Intron (SNP) | VAF 158/764 reads (21%) | catalogued as rs766318093; called by muse, mutect2, varscan2
- EP400P1 | n.461C>A | RNA (SNP) | VAF 83/415 reads (20%) | called by muse, mutect2, varscan2
- MIRLET7C | n.31T>G | RNA (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- NDRG4 | c.37+699A>C | Intron (SNP) | VAF 160/753 reads (21%) | called by muse, mutect2, varscan2
- RPSAP52 | n.736A>G | RNA (SNP) | VAF 90/438 reads (21%) | called by muse, mutect2, varscan2
- SLC25A51P4 | n.716C>T | RNA (SNP) | VAF 92/488 reads (19%) | called by muse, mutect2, varscan2
- TFAP2D | c.-14C>T | 5'UTR (SNP) | VAF 48/606 reads (8%) | catalogued as rs1392133006, COSV50408008; called by muse, mutect2
- UVRAG | c.-33C>G | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
